Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7677, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7677-01A (Primary Tumor).

Microscopic

Sections demonstrate an infiltrating glioma with oligodendroglial features. The tumor exhibits multifocal regional in both cellularity and atypia, suggestive of anaplastic progression in a background low grade tumor. In some areas, the tumor appears less cellular and demonstrates classic low grade oligodendroglial features including round nuclei with mild atypia and prominent perinuclear halos. In other areas, the neoplasm exhibits marked hypercellularity with more pronounced nuclear atypia. Numerous microgemistocytes are scattered throughout the tumor. The neoplastic cells diffusely infiltrate the adjacent brain. Areas of grey matter demonstrate foci with prominent perinuclear tumor satellitosis. The tumor exhibits scattered microcalcifications, myxoid change and thin branching vasculature. Neither necrosis, nor microvascular proliferation is seen. Although only 2 mitotic figures per 10 high power fields are counted, the previous biopsy demonstrated a MIB-1 labeling index of 24.5%, consistent with markedly elevated proliferative activity.

Diagnosis

Anaplastic oligodendroglioma grade III

Source: NCI Genomic Data Commons file f640af68-684f-4e45-b054-52e5bd979d36 (TCGA-HT-7677.816EA52A-DCA4-48F4-8FBB-4A6FF64D1FB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).